Somatic mutation profile of tumor specimen TCGA-A5-A2K4-01A (aliquot TCGA-A5-A2K4-01A-11D-A18P-09) from TCGA case TCGA-A5-A2K4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 69.2 years (25,270 days).
Specimen TCGA-A5-A2K4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33bd0246-4352-4137-b041-18ca760bf1aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A2K4-10B (Blood Derived Normal), aliquot TCGA-A5-A2K4-10B-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a008593-96ff-4705-92a5-136bbd0b6f36

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, RNA 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387356833, COSV55945226, COSV55959906; called by muse, mutect2, varscan2
- ACTRT1 | c.1071G>T p.W357C | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1330623592, COSV64419219; called by muse, mutect2
- AGO2 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99596592; called by muse, mutect2, varscan2
- C1orf94 | c.1418C>T p.T473M (on ENST00000488417 / NM_001134734.2; = p.T283M on NM_032884.5) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); catalogued as rs140728068; called by muse, mutect2, varscan2
- CLYBL | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs540417575, COSV100185810; called by muse, mutect2, varscan2
- DPH1 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs757704030, COSV99559741; called by muse, mutect2, varscan2
- DRAM1 | c.656T>C p.F219S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99315894; called by muse, mutect2, varscan2
- ELFN2 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101297460; called by muse, mutect2, varscan2
- FAHD2B | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1426534573, COSV55631488; called by muse, mutect2, varscan2
- JMJD1C | c.2942T>G p.L981R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100550910; called by muse, mutect2
- MAP3K13 | c.2348G>A p.G783D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99408139; called by muse, mutect2, varscan2
- NIPSNAP3A | c.273T>C p.D91= | Splice Region (SNP) | VAF 7/34 reads (21%) | catalogued as COSV101046503; called by muse, mutect2, varscan2
- NOTCH1 | c.3034G>A p.G1012S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776957107, COSV99492533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP2R5C | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.283); catalogued as COSV100159997; called by muse, mutect2, varscan2
- PSG5 | c.423C>G p.N141K | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV61654679; called by muse, mutect2, varscan2
- SLITRK3 | c.1931T>G p.F644C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.135); catalogued as COSV99580336; called by muse, mutect2, varscan2
- TOP1 | c.1919T>C p.F640S | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100793988; called by muse, mutect2
- ZBTB46 | c.182G>T p.C61F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99829765; called by muse, mutect2, varscan2
- CSMD3 | c.5602_5605+2del p.X1868_splice (on ENST00000297405 / NM_001363185.1; = p.X1764_splice on NM_052900.3) | Splice Site (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel*, varscan2
- APH1A | c.561C>T p.Y187= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs1553850081, COSV99354571; called by muse, mutect2, varscan2
- CAD | c.21G>A p.E7= | Silent (SNP) | VAF 8/166 reads (5%) | catalogued as COSV99255990; called by muse, mutect2
- FRMPD3 | c.1719G>A p.Q573= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99347281; called by muse, mutect2, varscan2
- METTL7B | c.243C>T p.T81= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99165252; called by muse, mutect2, varscan2
- PCDHB13 | c.2097G>A p.S699= | Silent (SNP) | VAF 43/158 reads (27%) | catalogued as rs1475218850, COSV99507979; called by muse, mutect2
- TMEM98 | c.192G>A p.L64= | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as rs1371749405, COSV55583364, COSV99912945; called by muse, mutect2
- ZNF407 | c.5001C>T p.F1667= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV55274715; called by muse, mutect2, varscan2
- AL590867.2 | n.144C>T | RNA (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
